Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANI, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AANI-01A (Primary Tumor).

[page 1 of 3]
Acc#

Ord #=

RESULTED

Collect D/T=

SURGICAL PATHOL

Modifiers:

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Left testicle

Clinical History
Not stated.

CHL ICD-O-3
Mixed teratoma & embryonal
Carcinoma 9081/3
Path
Mixed germ cell tumor 9085/3
Site @ Testis C62.9
Jr 3/31/14

Gross Description

Left testicle: Received in formalin and consists of a testis weighing 150 grams with attached spermatic cord. The spermatic cord measures 9 cm in length and 1.5 cm in diameter and the testicle measures 7.5 x 7 x 4 cm. The outer surface of the testis is inked black. The specimen is bivalved to reveal a variegated cut surface with multiple cysts and hemorrhage with the mass measuring 7 x 7 x 4 cm. The tumor does not invade the tunica albuginea. Representative sections are taken as follows:

- 1 spermatic cord margin
- 2 mid spermatic cord
- 3 spermatic cord near testicle
- 4 tumor to normal testis
- 5 tumor to spermatic cord
- 6-8 tumor to outer surface of testis
- 8

Date of Dictation:

Gross Description By:

Microscopic Description
Performed.

Final Pathologic Diagnosis

[page 2 of 3]
SURGICAL PATHOL

(Continued)

Acct#:

Left testicle:

- Mixed malignant germ cell tumor, 7 cm.
- Tumor predominant by immature teratoma
- Focal embryonal carcinoma (<5%) and yolk sac tumor (<10%)
- The tumor is limited to the testis and tunica albuginea.
- The spermatic cord is not involved and margin is negative.
- Lymphovascular invasion is not present.
- Remaining testicular tissue shows atrophy.

Pathologic Tumor Stage: pT1NXMX (Stage: IS)

Attending Pathologist:

***Electronically Signed Out By

Patient Name:

Case #:

Med. Rec. #:

Location:

Date Collected:

Pw TSS dx discrepancy form.
tumor is IT 90%
Embryonal 10%

Primary Malignancy History		☒

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	(Predominantly) immature teratoma, Embryonal Carcinoma <5%, Yolk Sac Tumor <10%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Teratoma (Immature) 90%, Embryonal Carcinoma 10%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 8f3608a3-c7f9-45a5-84d7-6352a1c7de7b (TCGA-XE-AANI.3995CD96-03E4-4A23-A5D3-4AD7BD23C4FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).